Somatic mutation profile of tumor specimen TCGA-ER-A196-01A (aliquot TCGA-ER-A196-01A-11D-A197-08) from TCGA case TCGA-ER-A196, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acral lentiginous melanoma, malignant; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 64.4 years (23,533 days).
Specimen TCGA-ER-A196-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70454e13-6665-446e-8358-9b45810092c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A196-10A (Blood Derived Normal), aliquot TCGA-ER-A196-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f9d6fb6-f1bf-49db-8f8b-a9a2a12a4ced

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN3A3 | c.158A>C p.H53P | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV55072539; called by muse, mutect2, varscan2
- DSG3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs377262567; called by mutect2, varscan2
- FRY | c.3608G>A p.C1203Y | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV66572870; called by muse, mutect2, varscan2
- GALNT8 | c.354del p.F119Sfs*72 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV99363349; called by mutect2, pindel, varscan2
- GORASP1 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs1476400660, COSV57186388; called by muse, mutect2
- LPIN2 | c.77C>G p.T26S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55240974; called by muse, mutect2, varscan2
- NUP62 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV61312606; called by muse, mutect2, varscan2
- OR5T3 | c.579G>C p.M193I | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57379345, COSV57381362, COSV57381812; called by muse, mutect2, varscan2
- PARP14 | c.2465C>G p.A822G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV71734967; called by muse, mutect2, varscan2
- STRIP1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs762142372, COSV63929704; called by mutect2, varscan2
- TTN | c.35908C>T p.P11970S (on ENST00000591111; = p.P4546S on NM_003319.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | PolyPhen benign (0.037); catalogued as COSV60153966; called by muse, mutect2, varscan2
- USP54 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV60444239; called by muse, mutect2, varscan2
- VPS13B | c.5013T>G p.N1671K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62147085; called by muse, mutect2, varscan2
- ZNF804B | c.2648T>C p.L883P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60835157; called by muse, mutect2, varscan2
- TMEM54 | c.211-3_211-2dup p.X71_splice | Splice Site (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel
- ZNF518B | c.2079del p.Q694Rfs*78 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- CACNG3 | c.411C>T p.S137= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs376566755, COSV50071550; called by mutect2, varscan2
- IGSF9 | c.1794C>T p.I598= (on ENST00000368094 / NM_001135050.2; = p.I582= on NM_020789.4) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV63638861; called by mutect2, varscan2
- LRRC75B | c.618G>A p.A206= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs767286236, COSV50641568; called by mutect2, varscan2
- RALGAPA2 | c.813C>A p.P271= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV99173258; called by muse, mutect2, varscan2
- ZNF275 | c.453C>T p.H151= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs782209488, COSV64704816; called by mutect2, varscan2
- ZNF804B | c.3735T>C p.P1245= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs746556845, COSV60835161; called by muse, mutect2, varscan2
